TCGA case TCGA-FE-A22Z — Thyroid Carcinoma (TCGA-THCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland; Tissue source site: Ohio State University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/78d14f86-896a-4f98-9274-b2e8e387add9

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 61 years; Vital status: Alive.

Diagnoses (4)
1. Papillary carcinoma, follicular variant (the primary disease): ICD-O-3 morphology code: 8340/3; ICD-10 code: C73; Tissue or organ of origin: Thyroid gland; Site of resection or biopsy: Thyroid gland; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 61.0 years (22,286 days); Year of diagnosis: 2007; AJCC staging edition: 6th; AJCC pathologic T: T4a; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IVA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 2,243 days (6.1 years); Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Extrathyroid extension: Moderate/Advanced (T4a); Lymph nodes positive: 5; Lymph nodes tested: 6; Measurement unit: Centimeters; Tumor depth measurement: 3; Tumor length measurement: 6.5; Tumor width measurement: 5.
   Treatment given: Treatment type: Radiation, Systemic; Days to treatment start: 103 days; Days to treatment end: 103 days; Treatment outcome: Partial Response; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 194 days; Days to treatment end: 257 days; Treatment dose: 6,600 cGy; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: I-131 Radiation Therapy; Treatment intent type: Adjuvant; Treatment dose: 217 mCi.
   Treatment given: Treatment type: I-131 Radiation Therapy; Treatment intent type: Adjuvant; Prescribed dose: 217; Prescribed dose units: mCi; Timepoint category: First Treatment.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.
2. Recurrence of diagnosis 1 (Papillary carcinoma, follicular variant), site: Lymph node, NOS. Age at diagnosis: 64.3 years (23,501 days); Days to diagnosis: 1,215 days (3.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 1,215 days (3.3 years).
   Recorded as not given: I-131 Radiation Therapy, for recurrent disease; Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
3. Metastasis of diagnosis 1 (Papillary carcinoma, follicular variant), site: Lung, NOS. Age at diagnosis: 66.7 years (24,358 days); Days to diagnosis: 2,072 days (5.7 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
4. Recurrence of diagnosis 1 (Papillary carcinoma, follicular variant), site: Connective, subcutaneous and other soft tissues, NOS. Age at diagnosis: 66.7 years (24,379 days); Days to diagnosis: 2,093 days (5.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 2,120 days (5.8 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.

Follow-up (8 entries)
- Day 1,215 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Lymph node, NOS; Days to recurrence: 1,215 days (3.3 years); Evidence of recurrence type: Histologic Confirmation; Histologic progression: No.
- Days to follow up: 1,566 days (4.3 years); Disease response: Tumor Free.
- Days to follow up: 1,799 days (4.9 years); Disease response: With Tumor.
- Day 2,072 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 2,072 days (5.7 years); Evidence of progression type: Convincing Image Source; Histologic progression: No.
- Day 2,093 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Connective, subcutaneous and other soft tissues, NOS; Days to recurrence: 2,093 days (5.7 years); Evidence of recurrence type: Histologic Confirmation; Histologic progression: No.
- Days to follow up: 2,243 days (6.1 years); Disease response: With Tumor.
- Disease response: Persistent Locoregional Disease; Timepoint: Within 3 Months of Surgery.
- Imaging type: MRI; Imaging anatomic site: Lymph Node; Timepoint: Preoperative.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FE-A22Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 130 mg.
  Slide TCGA-FE-A22Z-01A-01-TS1: Section location: Top; Percent tumor cells: 98; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 2; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-FE-A22Z-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FE-A22Z-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; History radiation exposure: No; Submitted tumor site: Thyroid; Histologic diagnosis: Thyroid Papillary Carcinoma - Follicular (>= 99% follicular patterned); Laterality: Left lobe; Lymph nodes preop imaging: Yes; Lymph nodes examined: Yes; Genotypic analysis detected: No.
- Neoplasm dimension: Tumor size width: 5.0; Tumor size width: 3.0.
- Lymph node preoperative assessment diagnostic imaging types: Lymph nodes preop imaging type: MRI with contrast.
- Follow-up form 1: I 131 radiation first treatment dose: 217 mCi; I 131 radiation treatment cumulative dose: 217 mCi; Clinical status within 3 mths surgery: Persistent locoregional disease; Tumor status: With tumor.
- Follow-up form 1, New tumor: New tumor event diagnosis confirmed by: Pathology; New tumor event histo progression: No; New tumor event type: Locoregional Recurrence; New tumor event site: Lymph Node Only; New tumor event node site: Lateral (levels 2-5); New tumor event treatment: Surgery (distant metastasis); New tumor event surgery: Yes; I 131 radiation first treatment method: Patient did not receive I-131 treatment; Radiation therapy xrt method prep: Patient Did Not Receive Radiation Therapy; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor; Radiation therapy xrt sensitizers: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,243 days; disease-specific survival: no event (censored), 2,243 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,215 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FE-A22Z-01A-11D-A16M-01): tumor purity 0.77, ploidy 2, whole-genome doublings 0.
